FM case AD17798 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/a01311c9-71e3-41ce-988d-efeb3fecde88

Female, 50.2 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
